Surgical pathology report (de-identified scan), TCGA case TCGA-TT-A6YP, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of Pennsylvania, specimen TCGA-TT-A6YP-01A (Primary Tumor).

[page 1 of 2]
Age:

Sex: Female

Print Date:

Date Collected

Date Received

Accession No.

Physician:

Copy to:

Surgical Pathology Report

Accession Number Collection Date/Time Received Date/Time Verified Date/Time Pathologist

Clinical Information

ar-old of von Hippel-Lindau disease, bilateral pheochromocytoma.

Pre-Operative Diagnosis: Not specified

Post-Operative Diagnosis: Not specified

Operation:

Specific questions to be answered:

Specimen:

- 1 Left Adrenal Gland
- 2 Right Adrenal Gland

Final Diagnosis

1. Left adrenal gland, 18.5g, excision:

- A. Pheochromocytoma, 5.8cm, confined to adrenal gland. See note.
- B. Surrounding brown fat.

2. Right adrenal gland, 29.9g, excision:

- A. Pheochromocytoma, 6.0cm, confined to adrenal gland. See note.
- B. Surrounding brown fat.

The case material was reviewed and the report verified by:

(Electronic signature)

Verification Date:

Note

PASS scores for these lesions are

left: 5 (abnormal mitoses; 3 mitoses/HPF and marked nuclear pleomorphism)

right: 3 (abnormal mitoses and marked nuclear pleomorphism).

Gross Description

The case is received in 2 fresh containers, each labeled with the patient's name and medical record number.

N/A

Name:
MRN:

Page 1 of 2

[page 2 of 2]
[REDACTED]
[REDACTED]
[REDACTED]
Age.

Sex: Female

Print Date

Date Collected

Date Received

Accession No. [REDACTED]

Physician:

Copy to:

Surgical Pathology Report

Accession Number	Collection Date/Time	Received Date/Time	Verified Date/Time	Pathologist
------------------	----------------------	--------------------	--------------------	-------------

Specimen 1 is designated "right adrenal gland" and consists of one adrenal and periadrenal adipose tissue weighing 18.5 g and measuring 6.1 x 3.0 x 7 cm total. the specimen is inked black. There is a 2.6 cm staple line. Serial sectioning reveals a tan and fleshy medullary based mass measuring 2.6 x 1.9 x 5.8 cm with focal hemorrhage. A portion is reserved for research and gross photographs are taken. The tissue immediately adjacent to the staple line is shaved and submitted in 1A and the remainder of the specimen is in 1B through 1J.

Specimen 2 is designated "right adrenal gland" and consists of one adrenal gland and peri-adrenal adipose tissue weighing 29.9 g and measuring 6.1 x 4.4 x 2.2 cm. The specimen is inked black. There are two linear 1.1 cm and 0.3 cm surgical defects in the serosal surface (gross photograph is taken). Serial sectioning reveals a grossly necrotic tumor, medullary based, measuring 6.0 x 3.0 x 2.2 cm with focal hemorrhage, necrosis, and a central 2.5 x 1.1 cm cystic area. A portion is reserved for research. The specimen is submitted in toto in 2A through 2M.

SUMMARY OF SECTIONS: 23, multiple, in toto

Dictated by.

Pathologist(s)

N/A

Source: NCI Genomic Data Commons file a4c80b5f-eec2-4c74-ba72-274b413c9d11 (TCGA-TT-A6YP.386CEECB-27D2-470F-B17F-166CE36E8BF8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).